Gene-level copy-number profile of tumor specimen TCGA-EE-A2GN-06A from TCGA case TCGA-EE-A2GN, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 72.3 years (26,421 days).
Specimen TCGA-EE-A2GN-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.82e8cdb8-d2ad-4320-a209-67be659bef05.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EE-A2GN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 410 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4c9ef741-f4de-4746-9b06-ff3982a279a1

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 3,933; copy number 2: 2,394; copy number 3: 24,511; copy number 4: 5,230; copy number 5: 16,828; copy number 6: 1,048; copy number 7: 5,261; copy number 8: 718; copy number 9: 119; copy number 10: 166; copy number 11: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EE-A2GN-06A-11D-A194-01): tumor purity 0.89, ploidy 2.44, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 6,264 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,541,768–234,324,511, 2,239 genes, copy number 7–8 (broad region; genes not listed).
- chr1:235,065,479–248,919,946, 329 genes, copy number 7 (broad region; genes not listed).
- chr6:167,607–14,646,638, 273 genes, copy number 7–8 (broad region; genes not listed).
- chr6:15,102,946–29,027,607, 351 genes, copy number 7–8 (broad region; genes not listed).
- chr6:30,743,790–43,288,258, 500 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr6:44,387,706–97,283,217, 633 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr7:11,820,317–14,974,777, 25 genes, copy number 8 (within-gene range 5–8): THRAP3P3, TMEM106B, VWDE, AC013470.3, AC013470.2, SSBL5P, TAS2R2P, AC013470.1, AC005281.1, SCIN, AC011891.2, AC011891.3, ARL4A, AC011891.1, AC011287.1, RN7SKP228, RBMX2P4, AC011287.2, AC005019.2, AC005019.1, ETV1, Y_RNA, RPL6P21, DGKB, EEF1A1P26.
- chr7:15,200,317–17,940,501, 37 genes, copy number 8 (within-gene range 6–8): AGMO, MEOX2, AC005550.2, LINC02587, AC005550.1, RPL36AP26, AC006041.2, AC006041.1, CRPPA, RPL36AP29, CRPPA-AS1, SOSTDC1, AC005014.3, LRRC72, AC005014.1, AC005014.2, ANKMY2, AC005014.4, BZW2, AC073333.1, TSPAN13, AGR2, AC073333.2, AGR3, RAD17P1, AC098592.2, AHR, AC098592.1, AC073332.1, BRWD1P3, Metazoa_SRP, AC019117.3, SNORA63, AC019117.2, AC019117.1, AC006482.1, SNX13.
- chr7:19,020,991–20,415,754, 20 genes, copy number 8: TWIST1, AC003986.2, AC003986.3, AC003986.1, FERD3L, AC007091.1, POLR1F, MIR3146, TMEM196, AC004543.1, AC005062.1, RPL21P75, AC007001.1, MACC1, MACC1-AS1, AC005083.1, AC099342.1, AC004130.2, ITGB8, AC004130.1.
- chr7:29,920,104–53,574,555, 399 genes, copy number 7–11 (within-gene range 6–11) (broad region; genes not listed).
- chr14:105,639,559–106,875,071, 193 genes, copy number 8 (broad region; genes not listed).
- chr15:72,114,258–101,933,350, 809 genes, copy number 7 (broad region; genes not listed).
- chr16:28,341,434–29,370,272, 1 gene, copy number 9 (within-gene range 5–9): AC009093.11.
- chr16:28,813,980–35,912,516, 455 genes, copy number 7–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,546. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
